Surgical pathology report (de-identified scan), TCGA case TCGA-43-6647, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-6647-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Level 1
- B. Level 7
- C. Level 4
- D. Level 2L
- E. Level 4L
- F. Level 8
- G. Level 12
- H. Level 7
- I. Right lower lobe
- J. Level 9
- K. Level 11
- L. 2R fat pad
- M. Middle lobe
- N. Bronchus intermedius proximal margin

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung carcinoma

FROZEN SECTION DIAGNOSIS

B - Frozen section and touch prep [REDACTED] e lymph nodal tissue negative for metastatic disease. [REDACTED] 0 [REDACTED]
[REDACTED] h nodal tissue negative for metastatic disease. [REDACTED]
[REDACTED] h nodal tissue negative for metastatic disease. [REDACTED]: [REDACTED]
[REDACTED] h nodal tissue negative for metastatic disease. [REDACTED]
[REDACTED] h nodal tissue negative for metastatic disease. [REDACTED]
[REDACTED] h nodal tissue negative for metastatic disease. [REDACTED] based on frozen section and touch preparation. [REDACTED]
I - Squamous [REDACTED] Mucosa and [REDACTED] in negative for tumor. [REDACTED]

GROSS DESCRIPTION

A. Received fresh labeled "level 1" are two soft pale tan white to tan gold tissues averaging 1.0 cm. in greatest dimension which are submitted in toto. AS-1.

B. Part B is received fresh for frozen section, labeled "level 7" and consists of two irregular portions of soft tan black tissue, the larger of which measures 1.2 x 0.6 x 0.2 cm. The smaller measures 1 x 0.7 x 0.2 cm. A touch preparation is made and the entire specimen is submitted in one block for frozen section.

C. Specimen received fresh for frozen section labeled "level 4" consists of multiple fragments of soft pink-black tissue measuring 1.5 x 1 x 0.4 cm in aggregate. All submitted for frozen section in one block.

D. Specimen received fresh for frozen section labeled "level 2L." It consists of fragments of soft tan tissue measuring 0.5 x 0.4 x 0.2 cm. All submitted for frozen section in one block.

E. Specimen is received fresh for frozen section labeled "4L." It consists of two irregular fragments of soft black tissue, one of which measures 5 x 4 x 2 mm. The other measures 4 x

[page 2 of 4]
3 x [REDACTED] It is all submitted in one block for frozen section.

F. Received fresh labeled "level 8" is a 0.7 cm. in greatest dimension slightly rubbery tan pink-gray tissue which is bisected and entirely submitted in one block. AS-1.

G. Received fresh labeled "level 12" are five fragmented soft pink-gray tissues ranging from 0.2 to 0.7 cm. in greatest dimension which are submitted in toto. AS-1.

H. Part H is received fresh for frozen section labeled "level 7". It consist of multiple fragments of soft tan and black tissue measuring 2.3 x 1.7 x 0.3 cm. in aggregate. Some of the tissue is focally firm. A touch preparation is made and the entire specimen is submitted in one block for frozen section.

I. Received fresh labeled "right lower lobe" is a 318 gram, 16.8 x 8.5 x 5.0 cm. lobectomy specimen with a stapled, 1 cm. in length, 1.4 x 1.1 cm. in diameter bronchial stump. A few soft tan gray tissues in keeping with lymph nodes measuring up to 0.9 cm. in greatest dimension are recovered from the hilar region. The pleura is smooth tan-pink-gray. There is a palpable, centrally cavitory, moderately well circumscribed, 6.0 x 5.0 x 5.0 cm. rubbery tan white tumor mass occupying the superior aspect of the specimen. The tumor appears to approach the pleura to within 0.1 cm. The tumor also approaches the hilum but the bronchial stump is without gross evidence of tumor at the margin. The hilar pleural is torn and disrupted in the vicinity of tumor, see block 15. A portion of tumor and a portion of normal are submitted for tissue procurement as requested. Frozen sections are also performed (see frozen section diagnosis - FSA tumor, FSB mucosa at bronchial margin). The wall of the bronchial stump is markedly calcified and a complete cross section could not be frozen. Instead, the mucosa is trimmed away from the margin and submitted for frozen section as FS2. The parenchyma superior to the lesion is markedly edematous (see block 9). The parenchyma throughout the remainder of the specimen is spongiform tan pink-red and no additional mass lesion or abnormality is identified. Representative sections are submitted in 12 blocks as labeled. RS-12.

BLOCK SUMMARY: 1 - Bronchial stump margin following light decalcification; 2 - vascular margins; 3-5 - tumor to inked intact and disrupted (block 5) pleura; 6, 7 - tumor to hilar structures (6 - bronchial stump, 7 - vascular structure); 8 - tumor to normal; 9-11 - ran [REDACTED] remainder of specimen; 12 - two whole hilar lymph nodes.

J. Received fresh labeled "level 9" are two soft pink-gray tissues averaging 0.3 cm. in greatest dimension which are submitted in toto. AS-1.

K. Received fresh labeled "level 11" are six intact to fragmented soft pink-gray tissues ranging from 0.3 to 0.6 cm. in greatest dimension which are submitted in toto. AS-1.

L. Received fresh labeled "2R fat pad" are three fragmented soft gray pink-gold tissues aggregating 1.7 x 1.3 x 0.3 cm. which are submitted in toto. AS-1.

M. Received fresh labeled "middle lobe" is a 7.8 x 7.5 x 2.9 cm. portion of lung tissue with a stapled 1 cm. length of apparent bronchus. A staple line is present along one aspect. The staple line is removed and the underlying surface is inked blue. Two soft tan-red tissues in keeping with lymph nodes measuring up to 1 cm. in greatest dimension are recovered from the vicinity of the bronchus. The pleura is smooth tan-pink. On sectioning, no discrete mass lesion is identified. The parenchyma is uniformly spongiform tan pink-red. Representative sections are submitted in eight blocks as labeled. RS-8.

BLOCK SUMMARY: 1 - Bronchial stump margin; 2-7 - random parenchyma; 8 - two whole lymph nodes.

[page 3 of 4]
[REDACTED]

N. Received fresh labeled "bronchus intermedius proximal margin" is a 1.5 x 1.3 x 1.0 cm. rubbery tan white tissue with multiple associated staples. The staples are removed. The specimen is entirely submitted in one block. AS-1. [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

A-H. Microscopic examination performed.

I.

Histologic type: Squamous cell carcinoma.
Histologic grade: Moderately differentiated.
Primary tumor (pT): The tumor measures 6 cm. in greatest dimension, pT2b. Central cavitation is present.
Margins of resection: The pleura and vascular margins are negative for tumor. The mucosa trimmed away from the bronchial margin and submitted for frozen section is negative for tumor. However, following decalcification, the complete cross section of the bronchus (which might be slightly distal to the actual resection margin) contains squamous cell carcinoma infiltrating the full thickness of the bronchus. It is difficult, therefore, to ascertain status of the actual surgical margin but carcinoma is at least quite close.

Direct extension of tumor: None identified.
Venous (large vessel) invasion: Negative.
Arterial (large vessel) invasion: Arterial invasion present, supported by stain for elastic on block #3.
Lymphatic (small vessel) invasion: Negative.
Regional lymph nodes (pN): In addition to the lymphoid tissue found in parts B-H and in J-M, this right lower lobe specimen contains five lymph nodes, one of which contains carcinoma by direct extension. (pN1)
Distant metastasis (pM): Cannot be assessed.
Other findings: There is a rare minute focus of acute bronchopneumonia. Also, between the tumor and the pleura there are foci of obstructive type pneumonia.

J-N. Microscopic examination performed.

14x5, 15, 64x2, 16, 5x2, 4x3, 3x9, 18

DIAGNOSIS

A. Level 1, excision - Fibrofatty tissue negative for tumor.
B. Level 7, excision - Lymphoid tissue with anthricosis, negative for tumor.
C. Level 4, excision - Lymphoid tissue with anthricosis, negative for tumor.
D. Level 2L, excision - Lymphoid tissue, negative for tumor.
E. Level 4L, excision - Lymphoid tissue, negative for tumor.
F. Level 8, excision - Reactive lymph node with anthricosis, negative for tumor.
G. Level 12, excision - Portions of lymphoid tissue with anthricosis, negative for tumor.
H. Level 7, excision - Portions of lymphoid tissue with anthricosis, negative for tumor.
I. Right lower lobe of lung, lobectomy - Right lower lobe of lung with 6 cm., cavitating moderately differentiated squamous cell carcinoma, with arterial invasion.
Bronchial margin at least suspicious for tumor.
Five peribronchial lymph nodes, one of which is positive for tumor by direct extension, 1/5.
Obstructive pneumonia and small foci of acute bronchopneumonia.
J. Level 9, excision - Two lymph nodes negative for metastatic disease, 0/2. K. Level 11, excision - Six lymph nodes all negative for metastatic disease, 0/6.

[page 4 of 4]
- [REDACTED]
- L. 2R fat pad, excision - Three lymph nodes all negative for metastatic disease, 0/3.
- M. Middle lobe, lobectomy - Right middle lobe, no significant pathology. Bronchial margin negative for tumor. Two peribronchial lymph nodes negative for metastatic disease, 0/2.
- N. Bronchus intermedius proximal margin, excision - Bronchus with marked calcification, negative for tumor.
- [REDACTED]
- [REDACTED]
- [REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 68c20258-2804-459e-96bb-c35cf624f86b (TCGA-43-6647.C4FEE0A5-5591-4466-8F65-D2E0BF29F990.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).